Somatic mutation profile of tumor specimen HCM-CSHL-0079-C25-01A (aliquot HCM-CSHL-0079-C25-01A-11D-A78M-36) from HCMI case HCM-CSHL-0079-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 75.9 years (27,727 days).
Specimen HCM-CSHL-0079-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bbdeebc-4d9b-4813-ba7f-809b8948b17d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0079-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-0079-C25-11A-11D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f7e45aa-96da-4faa-8d40-25690bff4495

The open-access MAF lists 50 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Nonsense Mutation 3, Intron 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JUP | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 86/460 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782440692, CM117932, COSV60278113; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 45/209 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 45/205 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 39/125 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060501195, CM043949, COSV52726068, COSV52741717, COSV53015551; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AHCY | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 75/452 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV104372538; called by muse, mutect2, varscan2
- ANKRD62 | c.725A>T p.D242V | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1248316493; called by muse, mutect2, varscan2
- CHRM4 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 84/441 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.246); catalogued as COSV63126418; called by muse, mutect2, varscan2
- COL16A1 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 63/362 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs780498909; called by muse, mutect2, varscan2
- DNAH11 | c.7471C>T p.R2491C | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs267601454, COSV60970751; called by muse, mutect2, varscan2
- EPHA6 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67563189, COSV67575954; called by muse, mutect2, varscan2
- FAT3 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780305849, COSV99968830; called by muse, mutect2, varscan2
- GTF3C3 | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.333); catalogued as rs1407489340, COSV55832163, COSV99826919; called by muse, mutect2, varscan2
- HOOK2 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 62/431 reads (14%) | catalogued as COSV99317923; called by muse, mutect2, varscan2
- KLF6 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 89/513 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99434942; called by muse, mutect2, varscan2
- MUC5AC | c.144dup p.P49Afs*71 | Frame Shift Ins (INS) | VAF 33/228 reads (14%) | catalogued as rs776704266; called by mutect2, pindel, varscan2
- NRXN3 | c.2038G>A p.E680K (on ENST00000335750 / NM_001330195.2; = p.E307K on NM_004796.6) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV59754688; called by muse, varscan2
- PIK3R1 | c.985C>A p.Q329K (on ENST00000521381 / NM_181523.3; = p.Q59K on NM_181504.4) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs1343600424, COSV57141568; called by muse, mutect2, varscan2
- PLCB3 | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs981845851, COSV54187917; called by muse, mutect2, varscan2
- PLCL1 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs780048494; called by muse, mutect2, varscan2
- RAD51B | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746531915; called by muse, mutect2, varscan2
- RERE | c.4487G>A p.G1496D | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100557304; called by muse, mutect2
- SSTR2 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1420669745, COSV100192098, COSV100192150; called by muse, mutect2, varscan2
- SYNE1 | c.16025C>T p.T5342M (on ENST00000367255 / NM_182961.4; = p.T5271M on NM_033071.3) | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs202105931; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- TBC1D14 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs776110416; called by muse, mutect2, varscan2
- TGFBR2 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1553630235, COSV55444513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRMT1 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs770329038, COSV99679285; called by muse, mutect2, varscan2
- USP40 | c.3184G>T p.E1062* | Nonsense Mutation (SNP) | VAF 30/193 reads (16%) | catalogued as COSV52488861; called by muse, mutect2, varscan2
- ZNF800 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV56175963; called by muse, mutect2, varscan2
- ARFGEF2 | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 88/527 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDCA3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNTLN | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- FRMD4A | c.1138T>C p.S380P | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PLXNB2 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHOH | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SLC15A1 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- ZCCHC8 | c.-14_2del | Translation Start Site (DEL) | VAF 28/182 reads (15%) | called by mutect2, pindel
- ARMCX5 | c.954C>T p.L318= | Silent (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- ATP4A | c.1629G>A p.E543= | Silent (SNP) | VAF 48/286 reads (17%) | called by muse, mutect2, varscan2
- COL9A3 | c.1134C>T p.R378= | Silent (SNP) | VAF 64/328 reads (20%) | catalogued as rs138208105; called by muse, mutect2, varscan2
- CYP11B1 | c.1302C>T p.S434= | Silent (SNP) | VAF 119/623 reads (19%) | catalogued as rs768226546, COSV52828210; called by muse, mutect2, varscan2
- GCK | c.543C>T p.V181= | Silent (SNP) | VAF 118/584 reads (20%) | catalogued as rs777964292, COSV60786759, COSV60787925; called by muse, mutect2, varscan2
- KLRD1 | c.66G>A p.S22= | Silent (SNP) | VAF 26/198 reads (13%) | catalogued as rs201930748, COSV60274515, COSV60274655; called by muse, mutect2, varscan2
- KNG1 | c.1296C>T p.G432= | Silent (SNP) | VAF 19/209 reads (9%) | called by muse, mutect2
- MC1R | c.357C>A p.V119= | Silent (SNP) | VAF 40/287 reads (14%) | catalogued as rs755222490, COSV59626464; called by muse, mutect2, varscan2
- PCLO | c.7872T>C p.P2624= | Silent (SNP) | VAF 22/172 reads (13%) | catalogued as COSV61613219; called by muse, mutect2, varscan2
- RBM20 | c.1365G>A p.S455= | Silent (SNP) | VAF 54/297 reads (18%) | catalogued as rs1414344349, COSV65706777; called by muse, mutect2, varscan2
- SLC22A13 | c.894T>C p.N298= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as rs751495301; called by muse, mutect2, varscan2
- TNRC6A | c.1293A>G p.V431= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs139673816; called by muse, mutect2, varscan2
- ADAMTS10 | c.1191-27C>T | Intron (SNP) | VAF 14/340 reads (4%) | catalogued as rs782467204; called by muse, mutect2
- C1QTNF9B | c.167-332G>A | Intron (SNP) | VAF 48/211 reads (23%) | catalogued as rs750294202; called by muse, mutect2, varscan2
